Gene-level copy-number profile of tumor specimen TCGA-41-2571-01A from TCGA case TCGA-41-2571, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 89.3 years (32,612 days).
Specimen TCGA-41-2571-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.41b29781-79e5-446c-89d2-39c565d48402.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-41-2571-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0f3ec8e-7b3f-4d15-88f7-3567a32dc54d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,900; copy number 2: 46,342; copy number 3: 1,493; copy number 4: 2,947; copy number 5: 67; copy number 17: 22; copy number 20: 13; copy number 25: 22; copy number 26: 8; copy number 27: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-41-2571-01A-01D-0911-01): tumor purity 0.78, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 137 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:49,524,208–55,211,628, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:46,383,652–46,876,784, 1 gene, copy number 26 (within-gene range 2–26): AC008014.1.
- chr12:46,404,644–46,832,408, 5 genes, copy number 26 (within-gene range 2–26): AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:57,619,527–57,772,119, 13 genes, copy number 20: SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1.
- chr12:68,746,125–69,579,793, 22 genes, copy number 25 (within-gene range 1–25): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2.
- chr12:69,738,860–69,855,363, 2 genes, copy number 26 (within-gene range 2–26): RAB3IP, AC025263.2.
- chr12:70,239,114–70,443,923, 5 genes, copy number 27: AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.
- chr16:54,542,808–55,586,666, 22 genes, copy number 17: LINC02183, AC007491.1, CRNDE, AC106742.1, IRX5, AC106738.1, AC106738.2, MTND5P34, AC109136.1, AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2.

Autosomal genes at a single copy (total copy number 1): 6,514. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
